Somatic mutation profile of tumor specimen TCGA-K7-AAU7-01A (aliquot TCGA-K7-AAU7-01A-11D-A382-10) from TCGA case TCGA-K7-AAU7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.5 years (22,476 days).
Specimen TCGA-K7-AAU7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f66548ac-87f6-41bc-adc0-052dbdf7e014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K7-AAU7-10A (Blood Derived Normal), aliquot TCGA-K7-AAU7-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5a8a0c9-a3f5-4e31-989d-03fa63087f5e

The open-access MAF lists 78 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 16, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 1, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABHD17B | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1193499434, COSV61009163; called by muse, mutect2, varscan2
- ACSS3 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1327521115, COSV54103707; called by muse, mutect2, varscan2
- ADRA1D | c.956A>C p.H319P | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101063010; called by muse, mutect2
- AEBP1 | c.1187A>T p.E396V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99788788; called by muse, mutect2, varscan2
- ALB | c.339_340insAGCA p.C114Sfs*9 | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | catalogued as COSV99891510; called by mutect2, pindel, varscan2
- ARNTL2 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 498/600 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99667794; called by muse, varscan2
- ATP4A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs200791532, COSV52866645; called by muse, mutect2, varscan2
- BCL11B | c.1510G>T p.E504* (on ENST00000357195 / NM_001282237.2; = p.E433* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100595555; called by muse, mutect2
- C8orf74 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs765461161, COSV100261971; called by muse, mutect2, varscan2
- CBLN1 | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV54653688, COSV99535673; called by muse, mutect2, varscan2
- CELSR3 | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99373573; called by muse, mutect2, varscan2
- CEP85 | c.2123T>A p.I708N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99432290; called by muse, mutect2, varscan2
- COP1 | c.1862A>T p.Q621L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100443319; called by muse, mutect2, varscan2
- CTTNBP2 | c.1693G>T p.V565F | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99353988; called by muse, mutect2, varscan2
- DMD | c.9164C>T p.T3055M | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs398124083, COSV58901782, COSV58923944; called by muse, mutect2, varscan2
- DUS4L | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV99143656, COSV99143777; called by muse, mutect2, varscan2
- FES | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs755326118, COSV51577247; called by muse, mutect2, varscan2
- GAN | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101633990; called by muse, mutect2, varscan2
- HECW1 | c.2026T>C p.S676P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.895); catalogued as COSV101223581; called by muse, mutect2, varscan2
- HERC2 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV99873927; called by muse, mutect2
- IGLON5 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99570703; called by muse, mutect2
- IMPDH1 | c.1369C>T p.P457S (on ENST00000470772 / NM_001142573.2; = p.P543S on NM_000883.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100118688; called by muse, mutect2, varscan2
- IZUMO1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs755650480, COSV99710804; called by muse, mutect2, varscan2
- LTBP1 | c.3166C>T p.L1056F (on ENST00000404816 / NM_206943.4; = p.L730F on NM_000627.4) | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV99698304; called by muse, varscan2
- LTBP3 | c.2226T>G p.C742W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100099692, COSV57241696; called by muse, mutect2
- MTSS1 | c.1367A>G p.Q456R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100274917; called by muse, mutect2, varscan2
- MVK | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.373); catalogued as rs200457031, COSV99949965; ClinVar: uncertain significance; called by muse, mutect2
- MYT1L | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101220783; called by muse, mutect2, varscan2
- NLRC3 | c.1427T>A p.F476Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072826; called by muse, mutect2, varscan2
- NPR2 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100438912; called by muse, mutect2, varscan2
- NT5E | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV100004162; called by muse, mutect2, varscan2
- ODAPH | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV100290181; called by muse, mutect2, varscan2
- OR9A2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV100628229; called by muse, mutect2, varscan2
- PCDHA7 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971500; called by muse, mutect2, varscan2
- PCDHA9 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs145248721; called by muse, mutect2, varscan2
- PDE4D | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs1034636680, COSV100506738, COSV61434360; called by muse, varscan2
- PDZD8 | c.1952T>G p.F651C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as COSV100559526; called by muse, mutect2, varscan2
- PLCB1 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100571129; called by muse, mutect2, varscan2
- PTPN14 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747732994, COSV100872594; called by muse, mutect2, varscan2
- RBM33 | c.3233G>T p.R1078L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs1019255866, COSV100355258, COSV62030829; called by muse, mutect2, varscan2
- RPL13 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 39/149 reads (26%) | catalogued as COSV99244947; called by muse, mutect2, varscan2
- SCARF2 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99839296; called by muse, mutect2, varscan2
- SEC23B | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99357707; called by muse, mutect2, varscan2
- SGPL1 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100940371; called by muse, mutect2, varscan2
- SLC6A15 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99880819; called by muse, mutect2, varscan2
- SLX4 | c.2563T>G p.Y855D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99568039; called by muse, mutect2, varscan2
- SMPD3 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54713378; called by muse, mutect2, varscan2
- SOX1 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs1307824177, COSV100446934; called by muse, mutect2
- TNKS2 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.088); catalogued as COSV100861090; called by muse, mutect2, varscan2
- TRAF7 | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV100399537; called by muse, mutect2, varscan2
- TTC38 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs751908725, COSV101123894; called by muse, mutect2, varscan2
- UBXN10 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100907783, COSV66772168; called by muse, mutect2, varscan2
- WDR18 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99242848; called by muse, mutect2, varscan2
- ZNF518A | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100283530; called by muse, mutect2, varscan2
- C8orf76 | c.867del p.N290Tfs*2 | Frame Shift Del (DEL) | VAF 81/166 reads (49%) | called by mutect2, pindel, varscan2
- FREM2 | c.1773_1781del p.D592_S594del | In Frame Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- GPR179 | c.6541G>A p.E2181K (on ENST00000621958; = p.E2180K on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- KMT2A | c.23del p.R8Pfs*20 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- NAT10 | c.436del p.L146* | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- AARS1 | c.1854G>A p.V618= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99933519; called by muse, mutect2, varscan2
- ADCY8 | c.564G>A p.L188= | Silent (SNP) | VAF 21/168 reads (13%) | catalogued as rs80098122, COSV99652407; called by muse, mutect2, varscan2
- AKAP12 | c.1485C>T p.G495= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs370245999; called by muse, mutect2, varscan2
- DCUN1D4 | c.435T>G p.A145= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100584513; called by muse, mutect2, varscan2
- ELAPOR1 | c.1557T>C p.S519= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100884436; called by muse, mutect2, varscan2
- FBH1 | c.1101C>T p.C367= (on ENST00000362091 / NM_178150.3; = p.C418= on NM_032807.4) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs780493608, COSV100758759; called by muse, mutect2, varscan2
- GAPVD1 | c.1557A>G p.L519= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs1265113458, COSV99783215; called by muse, mutect2, varscan2
- HPSE | c.1521C>T p.T507= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV100264359; called by muse, mutect2, varscan2
- HTR3B | c.25C>T p.L9= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1392501687, COSV99492001; called by muse, mutect2, varscan2
- IL7R | c.372C>T p.T124= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100285999, COSV57407753; called by muse, mutect2, varscan2
- MTNR1A | c.693A>G p.P231= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as COSV100208208; called by muse, mutect2, varscan2
- OR5L1 | c.132C>A p.G44= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV61735972; called by muse, mutect2, varscan2
- PLEKHA2 | c.195G>C p.S65= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101173419, COSV66242637; called by muse, mutect2, varscan2
- RESF1 | c.4815G>A p.R1605= | Silent (SNP) | VAF 1009/1339 reads (75%) | catalogued as COSV100440360; called by muse, mutect2, varscan2
- THY1 | c.312T>C p.C104= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99411468; called by muse, mutect2, varscan2
- TMEM132B | c.249T>C p.I83= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV54747095; called by muse, mutect2, varscan2
- CCN6 | c.590-1187T>C | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs1554314140, COSV100037048; called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109233 C>T | 5'Flank (SNP) | VAF 17/77 reads (22%) | catalogued as rs371414934; called by muse, mutect2, varscan2
